Somatic mutation profile of tumor specimen TCGA-2A-A8VL-01A (aliquot TCGA-2A-A8VL-01A-21D-A377-08) from TCGA case TCGA-2A-A8VL, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 51.1 years (18,658 days).
Specimen TCGA-2A-A8VL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a12bc43e-4212-46eb-bbc2-f70b8e39955e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2A-A8VL-10A (Blood Derived Normal), aliquot TCGA-2A-A8VL-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35c696c1-f91c-480b-88bc-31b638cef125

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 17, Silent 5, Nonsense Mutation 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDHPPT | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 9/59 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs370431948; called by muse, mutect2, varscan2
- ADAM18 | c.776G>A p.W259* | Nonsense Mutation (SNP) | VAF 19/91 reads (21%) | catalogued as COSV99695316; called by muse, mutect2, varscan2
- ADGRB3 | c.1763G>A p.R588Q | Missense Mutation (SNP) | VAF 37/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369405391, COSV65394023; called by muse, mutect2, varscan2
- ATG2B | c.25A>G p.I9V | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.952); catalogued as rs774028462, COSV100737896; called by muse, mutect2, varscan2
- DNHD1 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs771339647, COSV99599812; called by muse, mutect2, varscan2
- FRS3 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.723); catalogued as COSV99442753; called by muse, mutect2, varscan2
- GGT7 | c.1345G>T p.G449C | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as rs1367017511, COSV100321862; called by muse, mutect2, varscan2
- GRIK3 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs768148773, COSV100901773, COSV100902175; called by muse, mutect2, varscan2
- ITIH6 | c.2806C>A p.P936T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV99513126; called by muse, mutect2, varscan2
- LASP1 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58803170; called by muse, mutect2, varscan2
- LBH | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs766082860, COSV101257769; called by muse, mutect2, varscan2
- MYB | c.812A>T p.N271I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as COSV100214729; called by muse, mutect2, varscan2
- MYOM3 | c.3128A>G p.N1043S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV100141650; called by muse, mutect2
- NCOA6 | c.5954C>T p.A1985V | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV100749948; called by muse, mutect2
- NRG1 | c.1517C>T p.A506V (on ENST00000405005 / NM_013964.5; = p.A511V on NM_013956.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs572301736, COSV55166073; called by muse, mutect2, varscan2
- PLPPR5 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763977677, COSV54169272, COSV99587166; called by muse, mutect2, varscan2
- PRR23B | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.159); catalogued as rs376706999, COSV61494856; called by muse, mutect2, varscan2
- SVIL | c.4732G>A p.D1578N (on ENST00000355867 / NM_021738.3; = p.D1152N on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1379668931, COSV100881181; called by muse, mutect2, varscan2
- TMED10 | c.412-1G>C p.X138_splice | Splice Site (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100339780; called by muse, mutect2, varscan2
- TNFRSF8 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs749228869, COSV55794828; called by muse, mutect2, varscan2
- ADAMTS13 | c.2709G>A p.S903= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs782003158, COSV100747028, COSV63021832; called by muse, mutect2, varscan2
- C6 | c.1638C>A p.G546= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV99666873; called by muse, mutect2, varscan2
- CNTNAP2 | c.1335C>T p.I445= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as rs749205725, COSV62177596; ClinVar: likely benign; called by muse, mutect2, varscan2
- INTS2 | c.135T>G p.L45= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99247980; called by muse, mutect2, varscan2
- OR5D16 | c.744T>A p.T248= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV101003908; called by muse, mutect2, varscan2
